Somatic mutation profile of tumor specimen TCGA-D9-A3Z1-06A (aliquot TCGA-D9-A3Z1-06A-11D-A23B-08) from TCGA case TCGA-D9-A3Z1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.8 years (24,415 days).
Specimen TCGA-D9-A3Z1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 629c9457-eee7-4c25-bab6-3ab6d50a7c58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A3Z1-10A (Blood Derived Normal), aliquot TCGA-D9-A3Z1-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02de9cd7-94e2-470c-b2ac-9fe6285b50db

The open-access MAF lists 591 somatic variants for this specimen: 382 protein-altering or splice-affecting, 196 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 196, Nonsense Mutation 17, RNA 7, Intron 5, Splice Site 3, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 69/286 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- PKHD1 | c.11524C>T p.R3842* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as rs746471701, CM051192, COSV64380558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.144); catalogued as COSV54049524; called by muse, mutect2, varscan2
- ABCA10 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52217567; called by muse, mutect2
- ABCA10 | c.357T>G p.N119K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV52217588; called by muse, mutect2, varscan2
- ABCA8 | c.1374T>G p.D458E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV52193222; called by muse, mutect2, varscan2
- ABCC8 | c.3238G>A p.V1080I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs779183491, COSV56845601; called by muse, mutect2, varscan2
- ABCG8 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV55390222, COSV55395842; called by muse, mutect2, varscan2
- ADAM12 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.367); catalogued as COSV64101808; called by muse, mutect2, varscan2
- ADAMTS18 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1249046298, COSV51398246; called by muse, mutect2, varscan2
- ADAMTS18 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs758594316, COSV51398250; called by muse, mutect2, varscan2
- ADGRV1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs1554069089, COSV67977468; called by muse, mutect2, varscan2
- ADGRV1 | c.16709C>T p.P5570L | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV67977472; called by muse, mutect2, varscan2
- AFP | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56923673; called by muse, mutect2, varscan2
- AHR | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV54121264, COSV99619199; called by muse, mutect2, varscan2
- AK9 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868260985, COSV53419508; called by muse, mutect2
- AKAP6 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV55203268; called by muse, mutect2, varscan2
- AKAP6 | c.5870T>C p.V1957A | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV55203276; called by muse, mutect2, varscan2
- ALK | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66555643, COSV66569043; called by muse, mutect2
- AMIGO1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV63990210; called by muse, mutect2, varscan2
- ANAPC7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV71443648; called by muse, mutect2, varscan2
- ANGPTL1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs753785242, COSV52365065; called by muse, mutect2, varscan2
- ANP32A | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV51189290; called by muse, mutect2, varscan2
- APOA1 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV52635163; called by muse, mutect2, varscan2
- APOB | c.13301C>A p.S4434Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51921445; called by muse, mutect2, varscan2
- APOB | c.10744G>A p.E3582K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV51921456; called by muse, mutect2
- AQR | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV50029386; called by muse, mutect2, varscan2
- AREG | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV52644463; called by muse, varscan2
- AREG | c.475T>C p.C159R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52644474; called by muse, mutect2, varscan2
- ARHGAP20 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV52805929, COSV99503010; called by muse, mutect2, varscan2
- ARHGAP22 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374843400, COSV50932392; called by muse, mutect2, varscan2
- ATP12A | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV54511744; called by muse, mutect2, varscan2
- ATRIP | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs986630610, COSV99604008; called by muse, mutect2, varscan2
- ATRNL1 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs782568719, COSV100745433; called by muse, mutect2
- ATRNL1 | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100745434; called by muse, mutect2, varscan2
- BAHCC1 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1181730033; called by muse, mutect2
- BEST3 | c.1985A>T p.E662V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV58298377; called by muse, mutect2
- BMPR1A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs1053423400, COSV64404797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BOLA1 | c.251_253del p.Q84del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs782571719; called by mutect2, pindel, varscan2
- BRWD1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100313404; called by muse, mutect2, varscan2
- C6orf58 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as COSV61665897; called by muse, mutect2
- CA10 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.551); catalogued as COSV53335758, COSV53350680; called by muse, mutect2, varscan2
- CABP5 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53151862; called by muse, mutect2, varscan2
- CATSPERB | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV99831262; called by muse, mutect2, varscan2
- CATSPERB | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99831265; called by muse, mutect2, varscan2
- CAVIN2 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV58423129, COSV58425038; called by muse, mutect2, varscan2
- CAVIN4 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56866461; called by muse, mutect2, varscan2
- CCDC87 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV59578204; called by muse, mutect2, varscan2
- CCDC92 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as COSV53018403; called by muse, mutect2, varscan2
- CD209 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.857); catalogued as COSV52649129; called by muse, varscan2
- CD84 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs571102048, COSV60866595; called by muse, mutect2, varscan2
- CDH16 | c.1360-1G>A p.X454_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV55334541; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2, varscan2
- CDX4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV65171392; called by muse, mutect2, varscan2
- CEACAM6 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 85/519 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV52266306; called by muse, mutect2, varscan2
- CELSR1 | c.6821C>T p.P2274L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as rs1353398992, COSV53082675; called by muse, mutect2, varscan2
- CERCAM | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV65710385; called by muse, mutect2
- CFAP53 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV68351205, COSV68352864; called by muse, mutect2, varscan2
- CHD5 | c.5656C>T p.P1886S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs991361795, COSV52406738; called by muse, mutect2, varscan2
- CLDN18 | c.88T>G p.W30G | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100648251; called by muse, mutect2, varscan2
- CNTN1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755054882, COSV61635627; called by muse, mutect2, varscan2
- CNTN4 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1352228072, COSV61867020, COSV61872533; called by muse, mutect2, varscan2
- COL11A2 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.605); catalogued as COSV59493072; called by muse, mutect2, varscan2
- COL5A1 | c.2413G>A p.G805S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65664500; called by muse, mutect2, varscan2
- COPG1 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59112166; called by muse, mutect2, varscan2
- COQ3 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV54638745; called by muse, mutect2, varscan2
- CORO2A | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.065); catalogued as COSV59661819; called by muse, mutect2, varscan2
- CRB1 | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV66328486; called by muse, mutect2, varscan2
- CRELD1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs958797144, COSV55972102, COSV55973475; called by muse, mutect2, varscan2
- CRYBG1 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV64810290; called by muse, mutect2, varscan2
- CSMD2 | c.9434C>T p.S3145F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV53874473, COSV53882363; called by muse, varscan2
- CTNNA2 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58131789; called by muse, mutect2, varscan2
- CTSH | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV54983972; called by muse, mutect2, varscan2
- CUZD1 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100158919, COSV59025474; called by muse, mutect2, varscan2
- CYP2C19 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64906628; called by muse, mutect2, varscan2
- CYP3A7 | c.738A>G p.I246M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV60480308; called by muse, mutect2, varscan2
- CYP4X1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751911913, COSV64149538; called by muse, mutect2, varscan2
- DDA1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV63289309; called by muse, mutect2, varscan2
- DLEC1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57294458; called by muse, mutect2, varscan2
- DNAH10 | c.5699C>T p.T1900I (on ENST00000409039; = p.T1839I on NM_207437.3) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68987206; called by muse, mutect2, varscan2
- DNAH7 | c.10088C>T p.P3363L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56750055; called by muse, mutect2, varscan2
- DNAH7 | c.8405C>T p.S2802L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV56750064; called by muse, mutect2, varscan2
- DNER | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as COSV59159279; called by muse, mutect2
- DNTT | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs1477469177, COSV64522567; called by muse, mutect2, varscan2
- DPYS | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV60906017; called by muse, mutect2, varscan2
- DSG4 | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV57387667; called by muse, mutect2, varscan2
- DST | c.4691G>A p.G1564E | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.976); catalogued as COSV99755677; called by muse, mutect2, varscan2
- ECM1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV60871492; called by muse, mutect2
- EFCAB6 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53057304; called by muse, mutect2, varscan2
- EPS15L1 | c.1110C>T p.D370= | Splice Region (SNP) | VAF 8/53 reads (15%) | catalogued as COSV50167098; called by muse, mutect2, varscan2
- ERC2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55597408; called by muse, mutect2, varscan2
- ESYT3 | c.1285A>C p.T429P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV67440056; called by muse, mutect2, varscan2
- EVPL | c.3811G>C p.D1271H | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs775741673, COSV56906657; called by muse, mutect2
- EXOG | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs768205374, COSV55062554; called by muse, mutect2, varscan2
- F8 | c.2367C>G p.D789E | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV64269289; called by muse, mutect2, varscan2
- FAM131B | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68125394; called by muse, mutect2, varscan2
- FAM13A | c.2123G>A p.W708* | Nonsense Mutation (SNP) | VAF 64/357 reads (18%) | catalogued as COSV51995774; called by muse, mutect2, varscan2
- FAM160A2 | c.2159C>T p.P720L (on ENST00000449352 / NM_001098794.2; = p.P734L on NM_032127.4) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV56409269, COSV56413494; called by muse, mutect2, varscan2
- FAT3 | c.4787G>A p.G1596E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53071005; called by muse, mutect2, varscan2
- FGF17 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63925291; called by muse, mutect2, varscan2
- FGFBP1 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.129); catalogued as COSV52586008; called by muse, mutect2, varscan2
- FHOD1 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746584932, COSV50758511; called by muse, mutect2, varscan2
- FLG | c.3193G>A p.G1065R | Missense Mutation (SNP) | VAF 113/941 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV64235639; called by muse, mutect2, varscan2
- FLRT3 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV53939055; called by muse, mutect2, varscan2
- FMNL2 | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489348, COSV99979282; called by muse, mutect2
- FSD2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV58008391; called by muse, mutect2, varscan2
- FSTL5 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV60179082, COSV60198418; called by muse, mutect2, varscan2
- FUT10 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100161742, COSV59449582; called by muse, mutect2, varscan2
- FYB2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as rs1391645926; called by muse, mutect2, varscan2
- GABRP | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54661174; called by muse, mutect2, varscan2
- GCK | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.957); catalogued as COSV67883656; called by muse, mutect2, varscan2
- GLI2 | c.4471C>T p.P1491S (on ENST00000361492 / NM_001374353.1; = p.P1508S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV58033879; called by muse, mutect2, varscan2
- GPA33 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs774631325, COSV63300052; called by muse, mutect2, varscan2
- GPR107 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61276935; called by muse, mutect2
- GPR139 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58501455; called by muse, mutect2
- GPR179 | c.3790G>A p.E1264K (on ENST00000621958; = p.E1263K on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs376112804; called by muse, mutect2, varscan2
- GPRIN3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100310737; called by muse, mutect2
- GRIN3A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs145326290, COSV62450102; called by muse, mutect2, varscan2
- GSN | c.344G>C p.W115S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57994127; called by muse, mutect2, varscan2
- GTPBP1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450434263, COSV53283109; called by muse, mutect2
- GUCY1A2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as rs868075830, COSV56476306; called by muse, mutect2, varscan2
- GYS2 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV53920093; called by muse, mutect2, varscan2
- HCRTR2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1280067311, COSV63793406, COSV63793997; called by muse, mutect2, varscan2
- HEATR4 | c.2437G>C p.V813L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV58373496; called by muse, mutect2, varscan2
- HECW2 | c.3023C>A p.S1008Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV53647654; called by muse, mutect2, varscan2
- HEPHL1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV59889262; called by muse, mutect2, varscan2
- HEY2 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV64239296; called by muse, mutect2, varscan2
- HIP1 | c.144T>G p.I48M | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61182918; called by muse, mutect2, varscan2
- HRNR | c.2932G>A p.G978S | Missense Mutation (SNP) | VAF 57/467 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.437); catalogued as COSV64253600; called by muse, mutect2, varscan2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 43/244 reads (18%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2, varscan2
- HUWE1 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV53333008; called by muse, mutect2, varscan2
- ICAM3 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as COSV50328202; called by muse, varscan2
- IFIT3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51077788; called by muse, mutect2, varscan2
- IGF2BP1 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV51728467; called by muse, mutect2, varscan2
- IGF2BP2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs11558676, COSV60482390; called by muse, mutect2, varscan2
- IGHMBP2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs145237838; called by muse, mutect2, varscan2
- IGHV1-3 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs376335353; called by muse, mutect2, varscan2
- IGSF10 | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56781123; called by muse, mutect2, varscan2
- IGSF10 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | catalogued as COSV56781136; called by muse, mutect2, varscan2
- IGSF21 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs780315284, COSV52124444, COSV52125064, COSV52142184; called by muse, mutect2, varscan2
- IGSF21 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52124458; called by muse, mutect2, varscan2
- INO80 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100731816; called by muse, mutect2, varscan2
- INPP5F | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as rs1445230145, COSV100740122; called by muse, mutect2
- INPP5F | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as COSV100740123; called by muse, mutect2
- IPO5 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV55151805; called by muse, mutect2, varscan2
- IQCE | c.1571G>A p.R524K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.978); catalogued as COSV58076213; called by muse, mutect2, varscan2
- IQGAP1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV51581147; called by muse, mutect2, varscan2
- ITGAD | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369419074, COSV66756591; called by muse, mutect2, varscan2
- ITGB7 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV57237592; called by muse, mutect2, varscan2
- IVL | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100908202, COSV64215311; called by muse, mutect2, varscan2
- KCNB2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs747647219, COSV73048712; called by muse, mutect2, varscan2
- KCNE4 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56053951; called by muse, mutect2, varscan2
- KCNH1 | c.2948G>A p.R983K (on ENST00000271751 / NM_172362.3; = p.R956K on NM_002238.4) | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745322134, COSV55067407; called by muse, mutect2, varscan2
- KCNQ5 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59647751; called by muse, mutect2, varscan2
- KCNT2 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs901084344, COSV54062032; called by muse, mutect2, varscan2
- KIAA1328 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54446422; called by muse, mutect2, varscan2
- KIF20B | c.66T>G p.I22M | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV53301769; called by muse, mutect2, varscan2
- KLK8 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51590212; called by muse, mutect2, varscan2
- KMT2A | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV63281221; called by muse, mutect2, varscan2
- KRT16 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV56966823; called by muse, mutect2, varscan2
- KRTAP10-5 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs782465711, COSV59950184; called by muse, mutect2, varscan2
- KRTAP5-3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV101294510; called by muse, mutect2
- KSR1 | c.1016G>A p.R339Q (on ENST00000644974 / NM_001367810.1; = p.R202Q on NM_014238.2) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs757396791, COSV52027581; called by muse, mutect2
- LAMA2 | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV70337092; called by muse, mutect2, varscan2
- LILRA1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV52177427; called by muse, mutect2, varscan2
- LIN54 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61199788, COSV61203206; called by muse, mutect2, varscan2
- LINGO2 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV58056391, COSV58061271; called by muse, mutect2, varscan2
- LMAN2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100288373; called by muse, mutect2, varscan2
- LOXL1 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157933104, COSV56093331; called by muse, mutect2, varscan2
- LOXL4 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV53254825; called by muse, mutect2, varscan2
- LRCH2 | c.1879G>A p.G627R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.621); catalogued as COSV100407213, COSV57745026; called by muse, mutect2, varscan2
- LRP1B | c.5712G>T p.M1904I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs932656739, COSV67182183; called by muse, mutect2, varscan2
- LRP1B | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV101262115, COSV67182187; called by muse, mutect2, varscan2
- LRP6 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV53782765; called by muse, mutect2, varscan2
- LRRC46 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs144936742; called by muse, mutect2, varscan2
- LRRC7 | c.2306C>T p.P769L (on ENST00000651989 / NM_001370785.2; = p.P736L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50408847; called by muse, mutect2, varscan2
- LSS | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.327); catalogued as COSV62699759; called by muse, mutect2, varscan2
- LY75 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55101375; called by muse, mutect2, varscan2
- LYPLA2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); catalogued as COSV65720385; called by muse, mutect2, varscan2
- MAGEA6 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV61448610; called by muse, mutect2, varscan2
- MAGEE2 | c.1271G>A p.W424* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV64897146; called by muse, mutect2, varscan2
- MAGI2 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as rs758472567, COSV62631309; called by muse, mutect2, varscan2
- MAML3 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV72208473; called by mutect2, varscan2
- MAP7D2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs777528929, COSV65525394; called by muse, mutect2, varscan2
- MBL2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1449337298, COSV64757884; called by muse, mutect2, varscan2
- MBOAT7 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs770400629, COSV55473863; called by muse, mutect2, varscan2
- ME1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63837303; called by muse, mutect2, varscan2
- ME1 | c.663T>G p.Y221* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as COSV63837307; called by muse, mutect2, varscan2
- MFSD6L | c.1695T>G p.S565R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61687270; called by muse, mutect2, varscan2
- MPZL2 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | catalogued as COSV54048317; called by muse, mutect2, varscan2
- MUC16 | c.36287C>T p.S12096F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67440921, COSV67465048; called by muse, mutect2, varscan2
- MUC16 | c.29419C>T p.H9807Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67440927, COSV67494479; called by muse, mutect2, varscan2
- MXRA5 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV54222183; called by muse, mutect2, varscan2
- MYH4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV55111282; called by muse, mutect2
- MYO1F | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV100596688, COSV100597198; called by muse, mutect2
- NAT9 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52852368; called by muse, mutect2, varscan2
- NBEAL2 | c.6251C>T p.T2084I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52753528; called by muse, mutect2, varscan2
- NDST4 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs141541753, COSV52107688; called by muse, mutect2, varscan2
- NEB | c.7728G>A p.W2576* | Nonsense Mutation (SNP) | VAF 72/491 reads (15%) | catalogued as COSV50805883; called by muse, mutect2, varscan2
- NEDD1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV57141166; called by muse, mutect2, varscan2
- NELL2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61568074, COSV61571074; called by muse, mutect2
- NFATC1 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53694142; called by muse, mutect2, varscan2
- NISCH | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs146356041; called by muse, mutect2, varscan2
- NKAIN2 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs138663713; called by muse, varscan2
- NOS1AP | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV62631623; called by muse, mutect2, varscan2
- NOTCH3 | c.5029C>T p.P1677S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV54625173; called by mutect2, varscan2
- NR0B2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54259109; called by muse, mutect2, varscan2
- NRG3 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64541957; called by muse, mutect2, varscan2
- NWD1 | c.986A>C p.D329A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV60336851; called by muse, mutect2, varscan2
- OGDHL | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65100582; called by muse, mutect2, varscan2
- OPN1LW | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64063702; called by muse, mutect2, varscan2
- OR10J3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs777818775, COSV59953436, COSV59954444; called by muse, mutect2, varscan2
- OR10Z1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.561); catalogued as COSV63523706; called by muse, mutect2, varscan2
- OR11H12 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs534573876, COSV73569043; called by muse, mutect2
- OR2T27 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs747078103, COSV61280506; called by mutect2, varscan2
- OR2T27 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1269929469, COSV61283903; called by muse, mutect2, varscan2
- OR2W3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs766648870, COSV64455932; called by muse, mutect2, varscan2
- OR51A2 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV66748057; called by muse, mutect2, varscan2
- OR51A7 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63787954; called by muse, mutect2, varscan2
- OR56B4 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as COSV57203692; called by muse, mutect2, varscan2
- OR5J2 | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56620052; called by muse, mutect2, varscan2
- OR6C70 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV59244428; called by muse, mutect2, varscan2
- OR6K3 | c.283C>T p.P95S (on ENST00000368146; = p.P79S on NM_001005327.2) | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63745213; called by muse, mutect2, varscan2
- OR6V1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760856656, COSV69236835; called by muse, mutect2, varscan2
- OR8S1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs140344146; called by muse, mutect2, varscan2
- P2RY14 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs368040389; called by muse, mutect2
- PALD1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1051292295, COSV99698319; called by muse, mutect2, varscan2
- PAPLN | c.3104C>T p.S1035L (on ENST00000554301; = p.S1008L on NM_173462.4) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53712468; called by muse, mutect2, varscan2
- PCDH11Y | c.3494G>A p.C1165Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV53072691; called by muse, varscan2
- PCDHA8 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65322989; called by muse, varscan2
- PCDHA8 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.12); catalogued as rs782599276, COSV65322995; called by muse, varscan2
- PCDHB3 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50563883, COSV50577811; called by muse, mutect2, varscan2
- PCDHB7 | c.2336G>A p.R779K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1554280483, COSV50753507, COSV99176622; called by muse, mutect2, varscan2
- PDE1A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs747334904, COSV59513247; called by muse, mutect2, varscan2
- PDE4DIP | c.4166C>T p.S1389L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs782066972, COSV57671565; called by muse, mutect2, varscan2
- PDE5A | c.832-1G>A p.X278_splice | Splice Site (SNP) | VAF 18/129 reads (14%) | catalogued as COSV53344890; called by muse, mutect2, varscan2
- PITPNB | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV58060404; called by muse, mutect2, varscan2
- PKHD1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV61858441; called by muse, mutect2, varscan2
- PLCE1 | c.305T>A p.L102H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV53335238; called by muse, mutect2, varscan2
- PLEKHA7 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.1); catalogued as COSV63043303; called by muse, mutect2, varscan2
- PLG | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.052); catalogued as rs990943130, COSV57512257; called by muse, mutect2, varscan2
- PLXNC1 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571154689, COSV51568646; called by muse, mutect2, varscan2
- PMFBP1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52820013, COSV52831560; called by muse, mutect2, varscan2
- PMFBP1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV52820040; called by muse, mutect2, varscan2
- PNLIP | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1250314817, COSV65039564; called by muse, mutect2, varscan2
- PPTC7 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV62825636, COSV62825743; called by muse, mutect2, varscan2
- PRAG1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV58156924; called by muse, mutect2, varscan2
- PRB2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 66/536 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV66982018; called by muse, varscan2
- PRB2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 87/727 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs776738181, COSV66982036; called by muse, varscan2
- PRDM10 | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs755073250, COSV58798974; called by muse, mutect2, varscan2
- PRDM7 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV57985881; called by muse, mutect2, varscan2
- PRDM9 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.019); catalogued as rs1277802791, COSV57001777, COSV99689661; called by muse, mutect2, varscan2
- PRPF4 | c.281G>A p.R94Q (on ENST00000374198 / NM_001322267.2; = p.R95Q on NM_004697.5) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as rs1346629180, COSV65252162; called by muse, mutect2, varscan2
- PRUNE2 | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs546778607, COSV65037525; called by muse, mutect2, varscan2
- PRUNE2 | c.4460G>A p.R1487Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754473099, COSV65037531; called by muse, mutect2, varscan2
- PSG8 | c.1097G>A p.W366* | Nonsense Mutation (SNP) | VAF 57/437 reads (13%) | catalogued as COSV60609159; called by muse, mutect2, varscan2
- PTCHD4 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.841); catalogued as COSV59776290; called by muse, mutect2, varscan2
- PTH2 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.407); catalogued as COSV54527748; called by muse, mutect2, varscan2
- PTPRK | c.3836C>T p.S1279F (on ENST00000368215 / NM_001291984.2; = p.S1280F on NM_002844.4) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100950438, COSV63890323; called by muse, mutect2, varscan2
- RABEP2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62868313; called by muse, mutect2, varscan2
- RADX | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as COSV65317617; called by muse, mutect2, varscan2
- RAP1GAP2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54570838; called by muse, mutect2, varscan2
- RASIP1 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55802104; called by muse, mutect2
- RNF19B | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.071); catalogued as COSV52386628; called by muse, mutect2, varscan2
- ROS1 | c.5827G>A p.E1943K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs866970127, COSV63850757; called by muse, mutect2, varscan2
- RPAP2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.757); catalogued as COSV72509127; called by muse, mutect2, varscan2
- RPUSD4 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770933393, COSV100028843, COSV53598671; called by muse, mutect2, varscan2
- RRP9 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV51752740; called by muse, mutect2, varscan2
- RSPH3 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV51921003; called by muse, mutect2, varscan2
- RTP2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV64078959; called by muse, mutect2
- RUNX1T1 | c.449C>T p.T150I (on ENST00000265814 / NM_001198628.1; = p.T123I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV56135992; called by muse, mutect2, varscan2
- RUNX1T1 | c.314C>T p.S105F (on ENST00000265814 / NM_001198628.1; = p.S78F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56136020; called by muse, mutect2, varscan2
- RYR1 | c.2464C>T p.L822F | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62087262, COSV62089852, COSV62090916; called by muse, mutect2, varscan2
- S100A12 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.308); catalogued as COSV64198950; called by muse, mutect2, varscan2
- SCTR | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs201617857, COSV99191770; called by muse, mutect2
- SELE | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV60973772; called by muse, mutect2, varscan2
- SERPINB10 | c.235-1G>A p.X79_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV53071648; called by muse, mutect2, varscan2
- SGCZ | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV65993367; called by muse, mutect2, varscan2
- SI | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100016156, COSV52264417; called by muse, mutect2, varscan2
- SIMC1 | c.2218C>G p.L740V (on ENST00000443967 / NM_001308196.1; = p.L325V on NM_198567.5) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV57899227; called by muse, mutect2, varscan2
- SIRPG | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53810138; called by muse, mutect2, varscan2
- SLC15A2 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs866528859, COSV55195491; called by muse, mutect2, varscan2
- SLC25A19 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV57466861; called by muse, mutect2, varscan2
- SLC28A1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.905); catalogued as COSV54476087; called by muse, mutect2, varscan2
- SLC2A9 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53315902, COSV53325733; called by muse, mutect2, varscan2
- SLC40A1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53721683; called by muse, mutect2, varscan2
- SLC6A11 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.515); catalogued as COSV54389345; called by muse, mutect2
- SLC8A3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs1166939823, COSV53687470; called by muse, mutect2, varscan2
- SLIT2 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs141844605, COSV56558132; called by muse, mutect2, varscan2
- SLITRK2 | c.2359T>A p.S787T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV59422621; called by muse, mutect2, varscan2
- SLITRK6 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68389209, COSV68391037; called by muse, mutect2, varscan2
- SLTM | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1190300955, COSV65847976; called by muse, mutect2, varscan2
- SMR3B | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs267600235, COSV59228355, COSV59229278; called by muse, mutect2, varscan2
- SNCAIP | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766577479, COSV54401099; called by muse, mutect2, varscan2
- SORT1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56663887; called by muse, mutect2, varscan2
- SPANXN5 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.114); catalogued as COSV64968611; called by muse, mutect2, varscan2
- SPTA1 | c.2990C>T p.T997I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1259006546, COSV63748156; called by muse, mutect2, varscan2
- STOML3 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747314352, COSV65509822; called by muse, mutect2, varscan2
- STPG3 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV58023509; called by muse, mutect2, varscan2
- SUGP2 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58254834; called by muse, mutect2, varscan2
- SULT1C3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs866697546, COSV61252236; called by muse, mutect2, varscan2
- SYN1 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99927054; called by muse, mutect2, varscan2
- SYN1 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99927475; called by muse, mutect2, varscan2
- SYNPO | c.2609C>T p.S870F (on ENST00000394243 / NM_001166208.2; = p.S626F on NM_007286.6) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs757628049, COSV56937879; called by muse, mutect2, varscan2
- SYT14 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV55048755; called by mutect2, varscan2
- SYT4 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs746235891, COSV54897974, COSV54900818; called by muse, mutect2, varscan2
- TACC2 | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1191759613, COSV57744805; called by muse, mutect2, varscan2
- TACC3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs914777196, COSV57602461; called by muse, mutect2, varscan2
- TACR3 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV59197417; called by muse, mutect2, varscan2
- TAS1R2 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64743417, COSV99057452; called by muse, mutect2, varscan2
- TCTE1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1377837536, COSV65254984; called by muse, mutect2, varscan2
- TDRD5 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV54238306; called by muse, mutect2, varscan2
- TEKT5 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs544288612, COSV51586345; called by muse, mutect2, varscan2
- TEX45 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV64462533; called by muse, mutect2, varscan2
- TGM5 | c.1934C>T p.P645L (on ENST00000220420 / NM_201631.4; = p.P563L on NM_004245.4) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55008307; called by muse, mutect2, varscan2
- THAP2 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV100350468; called by muse, mutect2, varscan2
- THBS1 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52949663; called by muse, mutect2, varscan2
- TLR4 | c.1453G>A p.E485K (on ENST00000355622 / NM_138554.5; = p.E445K on NM_003266.4) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1023995398, COSV62922298; called by muse, mutect2, varscan2
- TLR4 | c.2424G>A p.W808* (on ENST00000355622 / NM_138554.5; = p.W768* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100842833, COSV62922301; called by muse, mutect2, varscan2
- TLR9 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV62345332; called by muse, mutect2, varscan2
- TMC5 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs1171336806, COSV66864204; called by muse, mutect2, varscan2
- TMEM119 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV67188300; called by muse, mutect2, varscan2
- TMEM145 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV56623622; called by muse, mutect2, varscan2
- TMEM200A | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51648640, COSV51660625; called by muse, mutect2, varscan2
- TMEM89 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV56569804; called by muse, mutect2, varscan2
- TNR | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as rs776846663, COSV54867827; called by muse, mutect2, varscan2
- TRAIP | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.83); catalogued as rs867696847, COSV58912870; called by muse, mutect2, varscan2
- TREML2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762890750, COSV72438998; called by muse, mutect2
- TRPC4 | c.2908G>A p.E970K (on ENST00000379705 / NM_016179.4; = p.E975K on NM_003306.3) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); catalogued as COSV58989028; called by muse, mutect2, varscan2
- TRPC6 | c.2792G>A p.R931K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV60250596; called by muse, mutect2, varscan2
- TSGA10 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1321470254, COSV61821756; called by muse, mutect2, varscan2
- TTBK1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV52487803; called by muse, mutect2, varscan2
- TTF1 | c.2303T>C p.L768P | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57501958; called by muse, mutect2
- TTF1 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.158); catalogued as rs1470909958, COSV57501976; called by muse, mutect2, varscan2
- TTLL3 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV59613315; called by muse, mutect2, varscan2
- TTN | c.94700G>A p.G31567E (on ENST00000591111; = p.G24143E on NM_003319.4) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | PolyPhen possibly damaging (0.628); catalogued as rs867409180; called by muse, mutect2
- TTN | c.89209G>A p.E29737K (on ENST00000591111; = p.E22313K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | PolyPhen probably damaging (0.994); catalogued as COSV59862680, COSV60221710; called by muse, mutect2, varscan2
- TTN | c.20933G>A p.R6978K (on ENST00000591111; = p.R6051K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | PolyPhen benign (0); catalogued as COSV59862713; called by muse, mutect2, varscan2
- TTN | c.18549G>A p.M6183I (on ENST00000591111; = p.M5256I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | PolyPhen benign (0.001); catalogued as COSV59862723; called by muse, mutect2, varscan2
- TTN | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | PolyPhen probably damaging (0.996); catalogued as rs747867752, COSV59862739; called by muse, mutect2, varscan2
- UGT2B10 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55318333; called by muse, mutect2, varscan2
- UGT2B4 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59314982; called by muse, mutect2, varscan2
- UNK | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1303016392, COSV53138863; called by muse, mutect2, varscan2
- UPP2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777135988, COSV50046234; called by muse, mutect2, varscan2
- USP5 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99978581; called by muse, mutect2
- USP5 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs782594555, COSV57540761; called by muse, mutect2
- USP9Y | c.6377A>T p.H2126L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100168334; called by muse, mutect2, varscan2
- VAT1 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 105/490 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55895846; called by muse, mutect2, varscan2
- VPS16 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs376818050; called by muse, mutect2, varscan2
- WDR33 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.065); catalogued as COSV59245803; called by muse, mutect2, varscan2
- WDR6 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58243730; called by muse, mutect2, varscan2
- WDR90 | c.1213T>C p.F405L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV53465936; called by muse, mutect2
- WNT1 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV53295128; called by muse, mutect2, varscan2
- XIRP1 | c.4367G>A p.G1456E | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV61136654; called by muse, mutect2, varscan2
- XIRP2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV54679872; called by muse, mutect2, varscan2
- XRN1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53807272; called by muse, mutect2, varscan2
- YLPM1 | c.6301T>C p.W2101R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57814157; called by muse, mutect2, varscan2
- ZBBX | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV56781599, COSV56787291; called by muse, mutect2, varscan2
- ZC3H14 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51766570; called by muse, mutect2, varscan2
- ZEB1 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as COSV58035478; called by muse, mutect2, varscan2
- ZFHX4 | c.8888G>A p.G2963E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50478844, COSV99262938; called by muse, mutect2, varscan2
- ZNF329 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63771563; called by muse, mutect2, varscan2
- ZNF423 | c.2129C>T p.S710F (on ENST00000563137 / NM_001379286.1; = p.S702F on NM_015069.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV52175253; called by muse, mutect2, varscan2
- ZNF532 | c.1682C>G p.S561W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV60171625; called by muse, mutect2, varscan2
- ZNF578 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV69735865; called by muse, mutect2, varscan2
- ZNF608 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV60434855; called by muse, mutect2, varscan2
- ZNF649 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56813878; called by muse, mutect2, varscan2
- ZNF683 | c.1333C>T p.H445Y (on ENST00000403843; = p.H425Y on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV62873174; called by muse, mutect2, varscan2
- ZSCAN18 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.791); catalogued as COSV53729143; called by muse, mutect2, varscan2
- ASPSCR1 | c.372C>T p.I124= | Splice Region (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- COL9A1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- FAT2 | c.8055dup p.V2686Sfs*8 | Frame Shift Ins (INS) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- GSN | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGBP1P2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- PPIAL4A | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SDCCAG8 | c.354dup p.V119Cfs*5 | Frame Shift Ins (INS) | VAF 29/122 reads (24%) | called by mutect2, pindel, varscan2
- TRAV26-1 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ABCG8 | c.264C>T p.I88= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55390231; called by muse, mutect2, varscan2
- ACSM1 | c.981G>A p.Q327= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV54632733; called by muse, mutect2, varscan2
- ADAM28 | c.1746C>T p.F582= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV56097329; called by muse, mutect2, varscan2
- ADCY8 | c.1389C>T p.D463= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV53894846; called by muse, mutect2
- ADGRV1 | c.1293G>A p.A431= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs773901506, COSV67977462; called by muse, mutect2, varscan2
- AKAP13 | c.5247C>T p.F1749= (on ENST00000394518 / NM_007200.5; = p.F1753= on NM_006738.6) | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV63447424; called by muse, mutect2, varscan2
- ALDH1L1 | c.66G>A p.E22= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs978443491, COSV56410073; called by muse, mutect2, varscan2
- AMBRA1 | c.762C>T p.I254= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54047855; called by muse, mutect2, varscan2
- ANK3 | c.8346A>G p.K2782= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV55042409; called by muse, mutect2, varscan2
- ANKAR | c.2482C>T p.L828= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV55609024; called by muse, mutect2, varscan2
- ANKRD45 | c.570G>A p.G190= | Silent (SNP) | VAF 23/183 reads (13%) | catalogued as rs1336295515, COSV60960021; called by muse, mutect2, varscan2
- AP000311.1 | c.204C>T p.I68= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs267606117, COSV51707873; called by muse, mutect2, varscan2
- APOA2 | c.270C>T p.F90= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as rs752976925, COSV57153940; called by muse, mutect2, varscan2
- ATRIP | c.2013C>T p.P671= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV56496331; called by muse, mutect2, varscan2
- B3GLCT | c.1425C>T p.F475= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs1344692733, COSV58452891; called by muse, mutect2, varscan2
- BCL2L12 | c.738C>T p.F246= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs545979323, COSV55862162; called by muse, mutect2, varscan2
- BPIFC | c.1374C>T p.F458= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1186221264, COSV53277095; called by muse, mutect2, varscan2
- BTBD16 | c.1074C>T p.N358= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV53260433; called by muse, mutect2, varscan2
- C10orf120 | c.583C>T p.L195= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV61491579; called by muse, mutect2, varscan2
- C11orf24 | c.1293G>A p.K431= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV58504852; called by muse, mutect2, varscan2
- C2orf66 | c.192C>T p.F64= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV61098515; called by muse, mutect2, varscan2
- CASR | c.2094C>T p.F698= (on ENST00000490131; = p.F775= on NM_000388.4) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs767586088, COSV56133753; called by muse, mutect2, varscan2
- CBLC | c.633C>T p.F211= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs777975775, COSV54321121; called by muse, mutect2, varscan2
- CBX7 | c.222G>A p.P74= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs754221134, COSV53358262; called by muse, mutect2, varscan2
- CCDC141 | c.3051G>A p.V1017= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV55368041; called by muse, mutect2, varscan2
- CCDC7 | c.3093C>T p.F1031= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as COSV56535644; called by muse, mutect2, varscan2
- CD101 | c.2655C>T p.Y885= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV56715677; called by muse, mutect2, varscan2
- CD300LF | c.438G>A p.L146= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV56895424; called by muse, mutect2, varscan2
- CDH10 | c.2151G>A p.R717= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV52568276, COSV52586111; called by muse, mutect2, varscan2
- CDH16 | c.2055C>T p.I685= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs766156376, COSV55334532; called by muse, mutect2, varscan2
- CDKN2A | c.171C>T p.A57= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as rs876658199, COSV58687724, COSV58705214; ClinVar: likely benign; called by muse, mutect2
- CEP192 | c.3508C>T p.L1170= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV58059411; called by muse, mutect2, varscan2
- CHD5 | c.120C>T p.F40= | Silent (SNP) | VAF 41/273 reads (15%) | catalogued as rs953790685, COSV52406755; called by muse, mutect2, varscan2
- CHMP7 | c.672C>T p.A224= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as COSV57532106; called by muse, mutect2, varscan2
- CHRD | c.2604G>A p.G868= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV52604982; called by muse, mutect2, varscan2
- CKAP5 | c.2682C>T p.I894= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV56363437; called by muse, mutect2, varscan2
- CKAP5 | c.1716G>A p.K572= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV56363448; called by muse, mutect2, varscan2
- CLDN18 | c.87G>A p.Q29= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100648250; called by muse, mutect2, varscan2
- CLIC1 | c.135C>T p.T45= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs141106730; called by muse, mutect2
- CLIC6 | c.1452C>T p.I484= (on ENST00000360731 / NM_001317009.2; = p.I466= on NM_053277.3) | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs749912710, COSV62446986; called by muse, mutect2, varscan2
- CNBD1 | c.1218C>T p.S406= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs544425898, COSV73072233; called by muse, mutect2, varscan2
- CNGB3 | c.675C>T p.V225= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV60683876; called by muse, mutect2
- CNTN4 | c.1428C>T p.T476= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs761439283, COSV100639360, COSV61867029; called by muse, mutect2, varscan2
- CNTNAP2 | c.159C>T p.S53= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1458849922, COSV62140530; called by muse, mutect2, varscan2
- COL1A2 | c.993C>T p.G331= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs1428964638, COSV51952309; called by muse, varscan2
- COL6A3 | c.7866C>T p.F2622= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as COSV55078381; called by muse, mutect2, varscan2
- COPG1 | c.1665C>T p.I555= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV59112186; called by muse, mutect2, varscan2
- COPZ2 | c.327C>T p.F109= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV50057615; called by muse, mutect2
- CSMD3 | c.10653C>A p.R3551= (on ENST00000297405 / NM_001363185.1; = p.R3382= on NM_052900.3) | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV99833973; called by muse, mutect2, varscan2
- CSMD3 | c.9747C>T p.F3249= (on ENST00000297405 / NM_001363185.1; = p.F3080= on NM_052900.3) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs61754530, COSV52091126; called by muse, mutect2, varscan2
- CYP2C8 | c.75G>A p.R25= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs560886948, COSV64875896; called by muse, mutect2, varscan2
- CYP4Z1 | c.717C>T p.F239= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as COSV100497667; called by muse, mutect2, varscan2
- DACH1 | c.948G>A p.G316= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV57487495; called by muse, mutect2, varscan2
- DCHS1 | c.4806C>T p.S1602= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1247850543, COSV55029640; called by muse, mutect2, varscan2
- DEPDC5 | c.2046C>T p.F682= (on ENST00000400246; = p.F751= on NM_014662.5) | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV56690304; called by muse, mutect2, varscan2
- DHRS11 | c.252C>T p.I84= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs776410184; called by muse, mutect2, varscan2
- DIDO1 | c.4044C>T p.T1348= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV56612710; called by muse, mutect2, varscan2
- DNAH3 | c.3478C>T p.L1160= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV54500959; called by muse, mutect2, varscan2
- DNAH5 | c.10230G>A p.T3410= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs765000004, COSV54201418; called by muse, mutect2, varscan2
- DOCK6 | c.4194C>T p.I1398= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs865887401, COSV53910462; called by muse, mutect2, varscan2
- EEF1AKNMT | c.930G>A p.E310= (on ENST00000361735 / NM_015935.5; = p.E224= on NM_014955.3) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100675855; called by muse, varscan2
- EIF2AK2 | c.837C>T p.G279= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs773100266, COSV51794386, COSV51798299; called by muse, mutect2, varscan2
- ENPP7 | c.435G>A p.G145= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs143305291; called by muse, mutect2, varscan2
- FAM83C | c.474C>T p.I158= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV65581858; called by muse, mutect2, varscan2
- FCGBP | c.6582C>T p.F2194= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- FER1L6 | c.4257C>T p.S1419= | Silent (SNP) | VAF 27/194 reads (14%) | catalogued as COSV67547707; called by muse, mutect2, varscan2
- FPR1 | c.612C>T p.I204= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV59050813; called by muse, mutect2, varscan2
- FSD2 | c.345G>A p.R115= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs1414720355, COSV58008379; called by muse, mutect2, varscan2
- GAB4 | c.1152C>T p.I384= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs757955159, COSV68752823; called by muse, mutect2, varscan2
- GPR183 | c.141G>A p.V47= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV63116833; called by muse, mutect2, varscan2
- GRIP2 | c.1434G>A p.Q478= (on ENST00000619221; = p.Q381= on NM_001080423.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV56119396; called by muse, mutect2
- HECW1 | c.837G>A p.L279= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV67820651; called by muse, mutect2, varscan2
- HMGB4 | c.540G>A p.G180= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs867993003, COSV53886137, COSV99592732; called by muse, mutect2
- HPGDS | c.534G>A p.R178= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1313170853, COSV54772810; called by muse, mutect2, varscan2
- IGKV1-9 | c.97C>T p.L33= | Silent (SNP) | VAF 50/301 reads (17%) | catalogued as rs549156699; called by muse, mutect2, varscan2
- IQCE | c.496C>T p.L166= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs372270614, COSV58076201; called by muse, mutect2, varscan2
- ITLN2 | c.561C>T p.F187= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV63537324; called by muse, mutect2, varscan2
- JCAD | c.2496C>T p.I832= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV64757686; called by muse, varscan2
- KCNC3 | c.1989C>T p.P663= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV65386538; called by muse, mutect2, varscan2
- KCNIP1 | c.66C>T p.I22= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs754975322, COSV61079960; called by muse, mutect2, varscan2
- KIAA1217 | c.1053C>T p.I351= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV56811776; called by muse, mutect2, varscan2
- KIAA1217 | c.4842G>A p.L1614= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV56811797; called by muse, mutect2, varscan2
- KIAA1549 | c.3318G>A p.R1106= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1413236984, COSV54303992; called by muse, mutect2
- KIF2B | c.459C>T p.I153= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs749699324, COSV52126705, COSV52127659, COSV99274436; called by muse, mutect2, varscan2
- KIF9 | c.666C>T p.I222= | Silent (SNP) | VAF 55/378 reads (15%) | catalogued as COSV55517370; called by muse, mutect2, varscan2
- KLF10 | c.441C>T p.L147= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV53434679; called by muse, mutect2, varscan2
- KLHL18 | c.1422C>T p.S474= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV51743724; called by muse, mutect2, varscan2
- KRT71 | c.747G>A p.V249= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV57288802; called by muse, mutect2, varscan2
- KRTAP4-5 | c.276G>A p.R92= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV58351535; called by mutect2, varscan2
- KRTAP5-3 | c.672C>T p.S224= | Silent (SNP) | VAF 38/260 reads (15%) | catalogued as COSV101294509; called by muse, mutect2
- LAMA2 | c.318G>A p.K106= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV70337087; called by muse, mutect2, varscan2
- LHX4 | c.945C>T p.S315= | Silent (SNP) | VAF 65/226 reads (29%) | catalogued as COSV55372541; called by muse, mutect2, varscan2
- LILRB1 | c.363C>T p.I121= (on ENST00000427581; = p.I85= on NM_006669.6) | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV61115655; called by muse, mutect2
- LMAN2 | c.495C>T p.P165= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV57425087; called by muse, mutect2, varscan2
- LNX1 | c.897C>T p.V299= (on ENST00000263925 / NM_001126328.3; = p.V203= on NM_032622.2) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV55781557; called by muse, mutect2, varscan2
- LRP4 | c.1893C>T p.H631= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV66133750, COSV66139300; called by muse, mutect2, varscan2
- LRRC8A | c.921C>T p.T307= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV52183647; called by muse, mutect2, varscan2
- MAGEB6 | c.720C>T p.T240= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1261846187, COSV66871755; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2640C>T p.T880= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV51715417; called by muse, mutect2, varscan2
- MBTPS1 | c.567C>T p.I189= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV58569101; called by muse, mutect2, varscan2
- MLIP | c.1249C>T p.L417= | Silent (SNP) | VAF 43/245 reads (18%) | catalogued as rs1206643085, COSV51425249; called by muse, mutect2, varscan2
- MRPL15 | c.708C>T p.L236= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs549868458, COSV52636798; called by muse, mutect2, varscan2
- MYH7 | c.2322G>A p.E774= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1555337814, COSV62515816; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.5433G>A p.G1811= | Silent (SNP) | VAF 28/205 reads (14%) | catalogued as COSV67959127; called by muse, mutect2, varscan2
- MYO1F | c.3111C>T p.P1037= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100596687; called by muse, mutect2
- NBAS | c.4341C>T p.P1447= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs754074985, COSV55710933, COSV99869393; called by mutect2, varscan2
- NCAM1 | c.972G>A p.Q324= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs969913624, COSV57509598; called by muse, mutect2, varscan2
- NIBAN1 | c.1140C>T p.F380= | Silent (SNP) | VAF 20/219 reads (9%) | catalogued as rs867149952, COSV62282512; called by muse, mutect2
- NLRP1 | c.834C>T p.F278= | Silent (SNP) | VAF 32/258 reads (12%) | catalogued as rs369457449, COSV52557397; called by muse, mutect2, varscan2
- NLRP11 | c.72G>A p.Q24= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV64085417; called by muse, mutect2, varscan2
- NOS1 | c.3696C>T p.F1232= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs765524362, COSV57605786; called by muse, mutect2, varscan2
- NOVA1 | c.1323G>A p.G441= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57471481; called by muse, mutect2, varscan2
- OGDHL | c.837C>T p.T279= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1384903463, COSV65100586; called by muse, mutect2, varscan2
- OR10G4 | c.543G>A p.P181= | Silent (SNP) | VAF 50/287 reads (17%) | catalogued as rs776594449, COSV100304998, COSV57976449; called by muse, mutect2, varscan2
- OR13C4 | c.801C>T p.L267= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV52925639; called by muse, mutect2, varscan2
- OR1C1 | c.135C>T p.I45= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV68715316; called by muse, mutect2, varscan2
- OR2F2 | c.87C>T p.S29= | Silent (SNP) | VAF 35/257 reads (14%) | catalogued as rs1318077306, COSV68832462; called by muse, mutect2, varscan2
- OR2L2 | c.663C>T p.L221= | Silent (SNP) | VAF 38/280 reads (14%) | catalogued as COSV63547447; called by muse, mutect2, varscan2
- OR8B12 | c.160C>T p.L54= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV60910812, COSV60912688; called by muse, mutect2, varscan2
- ORAI2 | c.633C>T p.F211= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs144660402; called by muse, mutect2, varscan2
- OSMR | c.1074A>T p.I358= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV57080397; called by muse, mutect2, varscan2
- OTOF | c.3429G>A p.R1143= (on ENST00000272371 / NM_194248.3; = p.R396= on NM_004802.4) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55494701; called by muse, mutect2, varscan2
- OTUB1 | c.570C>T p.F190= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs532509714, COSV55356279; called by muse, mutect2, varscan2
- OVCH1 | c.804C>T p.P268= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs756268256, COSV100549051, COSV58958959; called by muse, mutect2, varscan2
- P2RX1 | c.654C>T p.L218= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs781507586, COSV56652648; called by muse, mutect2, varscan2
- PACC1 | c.1035A>G p.A345= | Silent (SNP) | VAF 52/179 reads (29%) | catalogued as COSV54785831; called by muse, mutect2, varscan2
- PALD1 | c.2256C>T p.Y752= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99698317, COSV99698577; called by muse, mutect2, varscan2
- PCDHGA5 | c.1296C>T p.L432= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV53892173; called by muse, mutect2, varscan2
- PCDHGA6 | c.663C>T p.V221= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1242744421, COSV53892186; called by muse, mutect2
- PDGFD | c.747G>A p.R249= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56367414; called by muse, mutect2, varscan2
- PEG3 | c.1716C>T p.F572= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs1274541478, COSV55623398, COSV55633172; called by muse, mutect2, varscan2
- PKP3 | c.2376G>A p.E792= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV58985711; called by muse, mutect2, varscan2
- PLIN3 | c.537C>T p.S179= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1184857543, COSV55733808, COSV99701567; called by muse, mutect2, varscan2
- POLRMT | c.2439C>T p.F813= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52111936; called by muse, mutect2
- POTEA | c.1383C>T p.I461= (on ENST00000519951 / NM_001005365.2; = p.I415= on NM_001002920.1) | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PPRC1 | c.3483C>T p.F1161= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV53382760; called by muse, mutect2, varscan2
- PRSS35 | c.426C>T p.F142= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV63800027; called by muse, mutect2, varscan2
- PTPRN | c.2382C>T p.F794= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV55345252; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1329C>T p.T443= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV51929917; called by muse, mutect2, varscan2
- RAB37 | c.141C>T p.I47= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as COSV61192011; called by muse, mutect2, varscan2
- RAB3B | c.606G>A p.K202= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV65433369; called by muse, mutect2, varscan2
- RBP3 | c.1359G>A p.L453= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs781942905; called by muse, mutect2, varscan2
- RELN | c.1420C>T p.L474= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1438871577, COSV58983753, COSV58990244; called by muse, mutect2, varscan2
- RIC8B | c.1281C>T p.F427= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV62692963; called by muse, mutect2, varscan2
- RNF123 | c.1686C>T p.I562= | Silent (SNP) | VAF 39/282 reads (14%) | catalogued as COSV59683886; called by muse, mutect2, varscan2
- RNF213 | c.7815C>T p.I2605= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1402207165, COSV60388707; called by muse, mutect2, varscan2
- S1PR2 | c.501C>T p.I167= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV58485097; called by muse, mutect2, varscan2
- SARM1 | c.1239G>A p.K413= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1161829609, COSV50229201; called by muse, mutect2, varscan2
- SCN10A | c.5355G>A p.L1785= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs1463206676, COSV71860077; called by muse, mutect2, varscan2
- SCN10A | c.2208C>T p.I736= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs754351607, COSV71860078; called by muse, mutect2, varscan2
- SCN5A | c.2700C>T p.I900= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs202103107, COSV61114859; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCTR | c.1242C>T p.H414= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV50026707; called by muse, mutect2, varscan2
- SEMA3G | c.1239C>T p.L413= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV51593352; called by muse, mutect2, varscan2
- SERAC1 | c.1086C>T p.I362= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV65595272; called by muse, mutect2, varscan2
- SHC2 | c.579C>T p.V193= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV52743431; called by muse, mutect2, varscan2
- SHKBP1 | c.1185C>T p.I395= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs770125764, COSV52537340; called by muse, mutect2, varscan2
- SIRPG | c.558G>A p.G186= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV53806074; called by muse, mutect2, varscan2
- SLC26A7 | c.471G>A p.V157= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV52585533; called by muse, mutect2
- SLC6A12 | c.972C>T p.F324= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV62883719; called by muse, mutect2, varscan2
- SLC6A5 | c.1842C>T p.F614= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs990123360, COSV54223003; called by muse, mutect2, varscan2
- SPATA20 | c.1200C>T p.Y400= (on ENST00000356488 / NM_001258372.1; = p.Y416= on NM_022827.4) | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV50065719; called by muse, mutect2, varscan2
- SPEN | c.5229C>T p.S1743= | Silent (SNP) | VAF 43/280 reads (15%) | catalogued as COSV65357173; called by muse, mutect2, varscan2
- SREBF2 | c.2568C>T p.P856= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV63330309; called by muse, mutect2
- STAB2 | c.3273C>T p.F1091= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs751626024, COSV66333499; called by muse, mutect2, varscan2
- STAG3 | c.2424C>T p.L808= | Silent (SNP) | VAF 44/261 reads (17%) | catalogued as COSV57927154; called by muse, mutect2, varscan2
- STK11IP | c.480C>T p.L160= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV55245281; called by muse, mutect2, varscan2
- SUCLG2 | c.246A>G p.L82= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV56201187; called by muse, mutect2, varscan2
- SUPT6H | c.3414G>A p.R1138= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV58924167; called by muse, mutect2, varscan2
- TAS1R2 | c.159C>T p.F53= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV64743422; called by muse, mutect2, varscan2
- TBC1D9 | c.801C>T p.S267= | Silent (SNP) | VAF 49/233 reads (21%) | catalogued as COSV71306715; called by muse, mutect2, varscan2
- TBCK | c.2250C>T p.I750= (on ENST00000273980 / NM_001163436.4; = p.I687= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV56751644; called by muse, mutect2, varscan2
- TCTN1 | c.1728C>T p.A576= (on ENST00000551590 / NM_001173975.3; = p.A562= on NM_024549.6) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV54370945; called by muse, mutect2, varscan2
- TEX14 | c.1995C>T p.S665= (on ENST00000240361 / NM_001201457.2; = p.S659= on NM_031272.5) | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as COSV53611002; called by muse, mutect2, varscan2
- THAP2 | c.669C>T p.T223= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100350470; called by muse, mutect2, varscan2
- TLR2 | c.1548G>A p.K516= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV52604751, COSV52605983; called by muse, mutect2, varscan2
- TRANK1 | c.6360G>A p.V2120= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57139232; called by muse, mutect2
- TRIM10 | c.156G>A p.E52= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as COSV64988827; called by muse, mutect2, varscan2
- TRPV5 | c.1869C>T p.F623= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs758731434, COSV54682761; called by muse, mutect2, varscan2
- TSPEAR | c.1083C>T p.F361= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs782037604, COSV59950152; called by muse, mutect2, varscan2
- TSPEAR | c.663G>A p.P221= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs781960229, COSV59950174; called by muse, mutect2, varscan2
- TTC25 | c.897A>G p.K299= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV66367440; called by muse, mutect2, varscan2
- TTC7A | c.933C>T p.F311= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV55408115; called by muse, mutect2, varscan2
- UBE3B | c.2301C>T p.I767= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV55090636, COSV99783958; called by muse, mutect2, varscan2
- UGT2B10 | c.669C>T p.F223= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV55318314, COSV99607898; called by muse, mutect2, varscan2
- UNC13C | c.5895G>A p.E1965= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs267604266, COSV52839962; called by mutect2, varscan2
- USP54 | c.3594C>T p.S1198= | Silent (SNP) | VAF 28/257 reads (11%) | catalogued as COSV60439341; called by muse, mutect2, varscan2
- USP9Y | c.6378C>T p.H2126= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100168338; called by muse, mutect2, varscan2
- VIM | c.540G>A p.E180= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs778785495, COSV56404600; called by muse, mutect2, varscan2
- VSNL1 | c.135C>T p.L45= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as rs773411175, COSV54596846; called by muse, mutect2, varscan2
- ZC3HC1 | c.465C>T p.F155= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV61296982; called by muse, mutect2
- ZKSCAN5 | c.2448C>T p.L816= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as COSV58741659; called by muse, mutect2, varscan2
- ZNF142 | c.1864C>T p.L622= (on ENST00000411696 / NM_001379660.1; = p.L422= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV68742838; called by muse, mutect2, varscan2
- ZNF311 | c.270G>A p.K90= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV65852798; called by muse, mutect2, varscan2
- ZNF483 | c.612G>A p.R204= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as rs758741779, COSV58514364; called by muse, mutect2, varscan2
- ZNF594 | c.177C>T p.L59= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV68384655; called by muse, mutect2, varscan2
- ZNF681 | c.207G>A p.R69= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs773072942, COSV68073302; called by muse, mutect2, varscan2
- ADD2 | c.1742-286G>C | Intron (SNP) | VAF 10/82 reads (12%) | catalogued as rs200714328, COSV100035603; called by muse, mutect2, varscan2
- AL136982.4 | n.357C>T | RNA (SNP) | VAF 40/311 reads (13%) | catalogued as rs1224728267; called by muse, mutect2, varscan2
- BTN2A3P | n.1712C>T | RNA (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.382C>T | RNA (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- CLCA3P | n.506G>A | RNA (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- DUXA | c.*1A>G | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs1420628868, COSV101617140; called by muse, mutect2, varscan2
- KDM4B | c.1115+989C>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs748126320, COSV99346376; called by mutect2, varscan2
- LPAL2 | n.221C>T | RNA (SNP) | VAF 20/131 reads (15%) | catalogued as rs752777423; called by muse, mutect2, varscan2
- MIR376B | n.34C>T | RNA (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- NLRP7 | c.2810+2738C>T | Intron (SNP) | VAF 17/148 reads (11%) | catalogued as rs1055434087, COSV100052620; called by muse, mutect2, varscan2
- TTN | c.10361-5569C>T | Intron (SNP) | VAF 26/148 reads (18%) | catalogued as COSV100611895; called by muse, mutect2, varscan2
- TTN | c.10360+4909T>C | Intron (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100611896; called by muse, mutect2, varscan2
- XIST | n.9896C>T | RNA (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
